MMRF case MMRF_1897 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4fdd7e1f-a30d-44f4-8f1b-21d9c43a8572

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Dead; Days to death: 237 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.6 years (21,041 days); ISS stage: III; Days to last known disease status: 237 days; Days to last follow up: 237 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 26 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 25 days; Days to treatment end: 61 days.

Follow-up (2 entries)
- Days to follow up: 0 days; ECOG performance status: 3.
- Follow-up contact recording only the day: day 237.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Serum Free Immunoglobulin Light Chain, Kappa 172 mg/dL.
- Beta 2 Microglobulin 11.6 µg/mL.
- M Protein 9.4 g/dL.
- Glucose 6.22 mmol/L.
- Immunoglobulin G 4.37 g/L.
- Immunoglobulin A 39.2 g/L.
- Calcium 2.78 mmol/L.
- C-Reactive Protein 13.5 mg/dL.
- Immunoglobulin M 0.21 g/L.
- Lactate Dehydrogenase 1.7 µkat/L.
- Hemoglobin 6.14 mmol/L.
- Leukocytes 11.3 ×10⁹/L.
- Total Protein 8.3 g/dL.
- Absolute Neutrophil 8.8 ×10⁹/L.
- Albumin 27 g/L.
- Blood Urea Nitrogen 18.2 mmol/L.
- Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL.
- Creatinine 420 µmol/L.
- Platelets 109 ×10⁹/L.

Other clinical attributes
- Day 0: Weight: 105 kg; Height: 191 cm.

Biospecimens (3 samples)
- Sample MMRF_1897_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1897_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
- Sample MMRF_1897_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
